Somatic mutation profile of tumor specimen 0DII48 from CCDI case PBBVRD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 14.6 years (5,328 days).
Specimen 0DII48: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb6bade2-1803-4ff3-b31c-9d785dd7413f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII3A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12f52eda-1529-4103-a502-381e78b88b6e

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAL | c.247C>T p.R83W (on ENST00000269162 / NM_001142339.3; = p.R160W on NM_182978.4) | Missense Mutation (SNP) | VAF 227/618 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1385987861; called by muse, mutect2, varscan2
- HUWE1 | c.8930C>G p.P2977R | Missense Mutation (SNP) | VAF 149/383 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53340116; called by muse, mutect2, varscan2
- PLK3 | c.1568G>C p.R523P | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1038238648, COSV100221015; called by muse, mutect2, varscan2
- SCP2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 220/561 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs773719700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A3 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV54368617; called by muse, varscan2
- TMTC2 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 350/656 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs138363219; called by muse, varscan2
- ADGRD1 | c.33_36del p.S12Gfs*63 | Frame Shift Del (DEL) | VAF 54/294 reads (18%) | called by mutect2, varscan2
- SEMA6D | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP43 | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 105/199 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- AGBL5 | c.502C>T p.L168= | Silent (SNP) | VAF 239/418 reads (57%) | catalogued as rs1478628864; called by muse, mutect2, varscan2
- SLC38A10 | c.1284C>T p.L428= | Silent (SNP) | VAF 75/208 reads (36%) | called by mutect2, varscan2
- DGKZ | c.-31C>T | 5'UTR (SNP) | VAF 44/269 reads (16%) | catalogued as rs1429875740; called by muse, mutect2
- SLC13A5 | c.1055+83T>C | Intron (SNP) | VAF 4/51 reads (8%) | catalogued as rs1232161954; called by muse, varscan2
- USP32P1 | n.334+959G>A | Intron (SNP) | VAF 56/396 reads (14%) | catalogued as rs766829154; called by muse, mutect2, varscan2
